Somatic mutation profile of tumor specimen TCGA-DJ-A3VJ-01A (aliquot TCGA-DJ-A3VJ-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VJ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nonencapsulated sclerosing carcinoma; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 22.8 years (8,341 days).
Specimen TCGA-DJ-A3VJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 514a6c7f-8c8f-4433-a816-5003b425a131.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VJ-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VJ-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c56746c-62f3-44f4-841c-9a3ba077ff58

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANGPTL4 | c.872T>A p.V291E | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV56844524; called by muse, mutect2, varscan2
- BIRC6 | c.6292A>T p.N2098Y | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196955; called by muse, mutect2, varscan2
- BPTF | c.4195A>G p.M1399V | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs200808758, COSV58833596; called by muse, mutect2, varscan2
- CATSPER4 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1367050825, COSV58792581; called by muse, mutect2, varscan2
- OR4A5 | c.199A>T p.I67L | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2
- APBA1 | c.1401C>T p.G467= | Silent (SNP) | VAF 103/345 reads (30%) | catalogued as COSV55223573; called by muse, mutect2, varscan2
